Gene-level copy-number profile of tumor specimen ALCH-B4B8-TTP1-A from ALCHEMIST case ALCH-B4B8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.3 years (25,663 days).
Specimen ALCH-B4B8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d460e130-9583-434d-8f2d-25cd47113512.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4B8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/fe1672c9-19b9-4a39-84fc-1c5442742cb3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 13,028; copy number 2: 38,185; copy number 3: 5,515; copy number 4: 2,070; copy number 5: 15; copy number 6: 14; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:128,462,439–128,493,201, 3 genes (within-gene range 0–1): DNAJB8, DNAJB8-AS1, GATA2.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr8:27,869,883–27,992,673, 5 genes (within-gene range 0–1): SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr11:72,700,474–72,708,565, 2 genes (within-gene range 0–2): ARAP1-AS2, RPS12P20.
- chr15:25,174,927–25,268,551, 46 genes (within-gene range 0–1): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1, SNORD115-45, SNORD115-46, SNORD115-47.
- chr15:41,828,095–41,848,155, 2 genes (within-gene range 0–1): JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–1): RNA5SP393.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr15:96,342,953–96,345,651, 1 gene: AC103746.1.
- chr16:2,091,436–2,097,026, 2 genes (within-gene range 0–2): AC009065.2, AC009065.5.
- chr16:4,748,239–4,767,624, 2 genes (within-gene range 0–2): ZNF500, Metazoa_SRP.
- chr16:85,489,813–85,490,831, 1 gene: AC133540.1.
- chr20:25,248,085–25,298,012, 3 genes (within-gene range 0–2): PYGB, AL121772.2, AL121772.3.
- chr22:18,605,355–18,625,289, 5 genes: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:86,342,547–86,743,675, 9 genes, copy number 5–6 (within-gene range 2–6): WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10.
- chr11:1,947,278–2,001,470, 7 genes, copy number 5: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr16:32,649,193–32,788,944, 13 genes, copy number 6: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr22:18,636,445–18,638,405, 1 gene, copy number 16: CA15P2.

Autosomal genes at a single copy (total copy number 1): 10,200. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
